Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7369, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7369-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) MARGIN #1, SKIN, BIOPSY: BENIGN SKIN, NEGATIVE FOR MALIGNANCY.
- 2) MARGIN #2, SKIN, BIOPSY: BENIGN SKIN, NEGATIVE FOR MALIGNANCY.
- 3) MARGIN #3, SKIN, BIOPSY: BENIGN SKIN, NEGATIVE FOR MALIGNANCY.
- 4) MARGIN #4, SKIN, BIOPSY: BENIGN SKIN, NEGATIVE FOR MALIGNANCY.
- 5) MARGIN, LEFT MANDIBLE, BIOPSY: FRAGMENTS OF FIBROUS TISSUE AND BONE, NEGATIVE FOR MALIGNANCY.
- 6) MARGIN, RIGHT MANDIBLE, BIOPSY: FRAGMENTS OF FIBROUS TISSUE AND BONE, NEGATIVE FOR MALIGNANCY.
- 7) MARGIN, RIGHT TONSIL, BIOPSY: FOCAL MODERATE DYSPLASIA, NEGATIVE FOR INVASIVE CARCINOMA.
- 8) MARGIN, LEFT FLOOR OF MOUTH, BIOPSY: BENIGN SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.
- 9) MARGIN, RIGHT FLOOR OF MOUTH, BIOPSY: BENIGN SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.
- 10) MARGIN #2, TONSIL, BIOPSY: MODERATE DYSPLASIA, NEGATIVE FOR INVASIVE CARCINOMA (SEE COMMENT #1).
- 11) MANDIBLE, RIGHT, RESECTION: MODERATELY-DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 4.7 CM IN GREATEST EXTENT, WITH EXTENSIVE MANDIBULAR INVASION, PRESENT 0.3 CM FROM THE SUPERIOR SURGICAL MARGIN, 0.8 CM FROM ANTERIOR SURGICAL MARGIN AND 0.7 CM FROM INFERIOR AND POSTERIOR SURGICAL MARGINS; PERINEURAL INVASION PRESENT; NEGATIVE FOR LYMPHOVASCULAR INVASION; 3 OF 5 LYMPH NODES POSITIVE FOR MALIGNANCY, 1 BY DIRECT EXTENSION, (SEE COMMENT).
- 12) LYMPH NODES, RIGHT NECK LEVELS 2,3, EXCISION: 18 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 13) SKIN, RIGHT UPPER LIP, EXCISION: LICHENOID REACTION WITH MUCOSAL ULCERATION, NEGATIVE FOR MALIGNANCY.

COMMENT #1: Dysplasia is best seen in the original frozen section.

[page 2 of 5]
COMMENT #2: These findings correspond to AJCC pathologic Stage IV A (pT4a,pN2b,pM n/a).

**Electronically Signed Out by [REDACTED] **

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) skin margin #1; 2) skin margin #2; 3) skin margin #3; 4) skin margin #4; 5) left mandible margin; 6) right mandible margin; 7) right tonsil margin; 8) left floor of mouth margin; 9) right floor of mouth margin; 10) tonsil margin #2; 11) right mandible gingival cancer; 12) right neck levels 2,3; 13) right upper lip lesion (stitch is superior)

GROSS DESCRIPTION:

1) SOURCE: Skin Margin #1

Received fresh is one fragment of skin measuring 5.1 x 0.3 x 0.3 cm. The specimen is inked blue and entirely submitted for frozen section evaluation.

Summary of sections: 1AFSC, skin margin #1, 1/1.

2) SOURCE: Skin Margin #2

Received fresh is one fragment of skin measuring 5.8 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section evaluation.

Summary of sections: 2AFSC, skin margin #2, 1/1.

3) SOURCE: Skin Margin #3

Received fresh is a fragment of skin measuring 7.3 cm in length x 0.3 x 0.3 cm in cross section. The specimen is inked blue and entirely submitted for frozen section evaluation.

Summary of sections: 3AFSC, skin margin #3, 1/1.

4) SOURCE: Skin Margin #4

Received fresh is one fragment of skin measuring 10.4 cm in length x 0.4 x 0.2 cm. The specimen is entirely submitted for frozen section evaluation.

Summary of sections: 4AFSC, skin margin #4, 1/1.

5) SOURCE: Left Mandible Margin

[page 3 of 5]
Received fresh is a fragment of soft tissue measuring 0.5 x 0.3 x 0.3 cm.
The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 5AFSC, left mandible margin, 1/1.

6) SOURCE: Right Mandible Margin

Received fresh is one fragment of soft tissue measuring 0.8 x 0.3 x 0.3 cm.
The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 6AFSC, right mandible margin, 1/1.

7) SOURCE: Right Tonsil Margin

Received fresh are two fragments of soft tissue measuring 1.6 x 0.6 x 0.4 cm in aggregate. The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 7AFSC, right tonsil margin, 2/1.

8) SOURCE: Left Floor of Mouth Margin

Received fresh is one fragment of soft tissue measuring 1.3 x 0.7 x 0.4 cm.
The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 8AFSC, left floor of mouth margin, 1/1.

9) SOURCE: Right Floor of Mouth Margin

Received fresh is a fragment of soft tissue measuring 1.7 x 1.0 x 0.4 cm.
The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 9AFSC, right floor of mouth margin, 1/1.

10) SOURCE: Tonsil Margin #2

Received fresh is a fragment of soft tissue measuring 3.4 x 0.3 x 0.3 cm.
The specimen is entirely submitted for frozen section evaluation.
Summary of sections: 10AFSC, 1/1.

11) SOURCE: Right Mandibular Gingival Cancer

Received fresh is a skin specimen with underlying bone and soft tissue. The overall specimen measures 8.3 cm from superior to inferior, 8.0 cm from anterior to posterior, and 4.0 cm from superficial to deep. Present on the surface of the specimen is an ovoid skin excision measuring 7.7 x 7.5 cm in horizontal dimension. At the center of this skin excision is a raised, variegated purple-black lesion measuring 4.7 x 4.0 x 0.6 cm. Numerous hair follicles are present protruding from this lesion. The specimen is inked in the following manner: superior-orange, inferior-yellow, deep-blue, anterior-black, posterior-green. The anterior and superior bony margins are trimmed and submitted. The specimen is serially sectioned to reveal invasion of the skin lesion into the subcutaneous tissue and focally into the underlying mandible. The lesion extends focally to the posterior/deep margin and focally to the superior margin. It extends to within 1.4 cm of the inferior margin. Sections through the anterior portion of the specimen reveals extension of the lesion to within 1.9 cm of the anterior margin. Representative sections are submitted. Bony fragments are decalcified prior

[page 4 of 5]
to submission.

Summary of sections: 11A, anterior/inferior bony margin, 1/1; 11B, superior margin, 1/1; 11C-11E, lesion invading bone, 1/1; 11F, lesion and posterior margin, 1/1; 11G, deep margin, 2/1; 11H, 11I, lesion and gingiva, bisected, 1/1 each; 11J, lesion and superior margin, 2/1; 11K, lesion and inferior margin, 1/1; 11L, lesion and anterior margin, 1/1; 11M, 11N, additional sections of lesion, 1/1 each.

12) SOURCE: Right Neck Levels 2, 3

Received fresh is one fragment of fibrous and fatty tissue measuring 7.1 x 3.3 x 1.7 cm. Candidate lymph nodes are identified and submitted.
Summary of sections: 12A, four candidate lymph nodes, 4/1; 12B, candidate lymph nodes, 6/1; 12C, 12D, two candidate lymph nodes, bisected, 2/1 each.

13) SOURCE: Right Upper Lip Lesion (stitch is superior)

Received fresh is an ellipse of skin measuring 1.89 x 1.4 cm in horizontal dimension and excised to a depth of 0.3 cm. The skin surface contains numerous hairs, as well as a light brown area measuring 0.5 x 0.3 cm. A suture is present designating the superior margin. This will be designated as 12 o'clock. The specimen is inked in the following manner: 11 o'clock to 5 o'clock-black, 5 o'clock to 11 o'clock-blue, deep-black. The specimen is sequentially sectioned from 12 o'clock to 6 o'clock and is entirely submitted.
Summary of sections: 13A, tips, 2/1; 13B, sequential sections, 4/1.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Skin Margin #1

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR LESION.

2) SOURCE: Skin Margin #2

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR LESION.

3) SOURCE: Skin Margin #3

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR LESION.

4) SOURCE: Skin Margin #4

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR LESION.

5) SOURCE: Left Mandible Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA.

[page 5 of 5]
6) SOURCE: Right Mandible Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

7) SOURCE: Right Tonsil Margin

FROZEN SECTION DIAGNOSIS: MODERATE DYSPLASIA [REDACTED]

8) SOURCE: Left Floor of Mouth Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

9) SOURCE: Right Floor of Mouth Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA. [REDACTED]

10) SOURCE: Tonsil Margin #2

FROZEN SECTION DIAGNOSIS: MODERATE DYSPLASIA, NEGATIVE FOR INVASIVE CARCINOMA. [REDACTED]

Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xDECALCIFICATION

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA [REDACTED]) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file e7282c86-92d9-425b-81e4-5c2c91f28b96 (TCGA-CR-7369.BA5D6185-C57D-45BD-958D-0F4AC8E8AE57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).